Surgical pathology report (de-identified scan), TCGA case TCGA-39-5021, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5021-01A (Primary Tumor).

[page 1 of 5]
Clinical Diagnosis & History:

Left upper lung mass, FNA (+) NSCLC.

Specimens Submitted:

- 1: SP: Level 5 mediastinal lymph nodes
- 2: SP: Left level 6 mediastinal lymph nodes
- 3: SP: Level seven mediastinal lymph nodes
- 4: SP: Left level eleven mediastinal lymph nodes
- 5: SP: Level five mediastinal lymph nodes
- 6: SP: Left posterior hilar level eleven lymph nodes
- 7: SP: Left level eleven interlobar nodes
- 8: SP: Left upper lobe lung

DIAGNOSIS:

- 1) LYMPH NODES, MEDIASTINAL, LEVEL V, EXCISION:
- FRAGMENT OF BENIGN LYMPH NODE.
- 2) MEDIASTINAL LYMPH NODES, LEFT, LEVEL VI, EXCISION:
- BENIGN FRAGMENTED LYMPH NODES.
- 3) MEDIASTINAL LYMPH NODES, LEVEL VII, EXCISION:
- BENIGN FRAGMENTED LYMPH NODES.
- 4) MEDIASTINAL LYMPH NODES, LEFT, LEVEL XI, EXCISION:
- BENIGN FRAGMENTED LYMPH NODE.
- 5) MEDIASTINAL LYMPH NODES, LEVEL V, EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 6) POSTERIOR HILAR LYMPH NODES, LEFT, LEVEL XI, EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 7) INTERLOBAR LYMPH NODES, LEFT, LEVEL XI, EXCISION:
- BENIGN FRAGMENTED LYMPH NODES.
- 8) LUNG, LEFT UPPER LOBE, LOBECTOMY:
- SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED, OF LEFT UPPER LOBE.
- THE TUMOR GREATEST DIAMETER IS > 3 CM (3.2 CM).

** Continued on next page **

[page 2 of 5]
- NO VASCULAR INVASION IS IDENTIFIED.
- NO PERINEURAL INVASION IS IDENTIFIED.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE TUMOR INVOLVES THE VISCERAL PLEURA.
- NO IN SITU CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC LUNG SHOWS THE FOLLOWING ABNORMALITY: APICAL SCAR.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF
METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED):
PERIBRONCHIAL: 0/8.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	MUCIN	
	EVG	

1) The specimen is received fresh for frozen diagnosis consultation and
labeled, "Level 5 mediastinal lymph nodes". It consists of multiple tan-red
soft tissue, measuring 1.0 x 0.8 x 0.5 cm in aggregate. The specimen is
submitted for frozen entirely.

Summary of sections:
FSC-frozen section control.

2) The specimen is received fresh for frozen diagnosis consultation and
labeled, "Left level 6 mediastinal lymph nodes". It consists of a piece of
tan-red soft tissue, measuring 1.5 x 1.0 x 0.6 cm. The specimen is
submitted for frozen entirely.

Summary of sections:
FSC-frozen section control.

3) The specimen is received fresh for frozen diagnosis consultation and
labeled, " Level seven mediastinal lymph nodes". It consists of seven lymph
nodes, measuring from 0.3 up to 1.0 cm in greatest dimension. The specimen
is submitted entirely for frozen.

** Continued on next page **

[page 3 of 5]
Summary of sections:
FSCA-frozen section control.
FSCB-frozen section control.
FSCC-frozen section control.

4) The specimen is received in formalin and labeled, "Left level eleven mediastinal lymph nodes". It consists of a gray-tan fragment of tissue measuring 1.8 x 0.5 x 0.1 cm. Entirely submitted in one block.

Summary of Sections:
LN - lymph node

5) The specimen is received in formalin and labeled, "Level five mediastinal lymph nodes". It consists of a fragment of tissue measuring 0.4 x 0.2 x 0.2 cm. Entirely submitted in one block.

Summary of Sections:
LN - lymph node

6) The specimen is received in formalin and labeled, "Left posterior hilar level eleven lymph nodes". It consists of two lymph nodes measuring 0.5 x 0.5 x 0.4 cm and 0.4 x 0.3 x 0.2 cm. Entirely submitted in two blocks.

Summary of Sections:
LN - lymph node

7) The specimen is received in formalin and labeled, "Left level eleven interlobar nodes". It consists of multiple fragments of gray-tan tissue measuring 0.7 x 0.5 x 0.5 cm in aggregate. Entirely submitted in three blocks.

Summary of Sections:
LN - lymph node

8) The specimen is received fresh and labeled, "Left upper lobe lung mass". It consists of a 154 gm lobe of lung measuring 15.2 x 8.7 x 2.8 cm. The posterior surface of the lobe reveals grossly unremarkable broncho-vascular margin. In addition, two stapled lines are noted, they are removed and inked black. The anterior surface of the lobe shows puckered pleura on the lateral aspect of the lung parenchyma. The puckered area is inked blue. Sectioning through the lung parenchyma reveals a firm, well-circumscribed gray-tan tumor measuring 3.0 x 3.2 x 2.1 cm, located at the lateral aspect of the lobe, and it is 3.2 cm away from the bronchial resection margin. Grossly, it does not involve large airways. A nodule

** Continued on next page **

[page 4 of 5]
----- Page 4 of 5
measuring 0.7 x 0.5 x 0.4 cm, is noted at the apex of the lobe, it is irregular and gray-tan in appearance. Grossly, it does not look like the tumor. Representative sections are submitted in thirteen blocks. A photograph is taken and the tissue submitted for TPS.
Summary of Sections: BVM - bronchial vascular margin
LN - lymph node
TM - tumor
SM - stapled margin
NL - normal lung
NO - nodule

Summary of Sections:

Part 1: SP: Level 5 mediastinal lymph nodes [REDACTED] [REDACTED]

Block	Sect.	Site	PCs
1		fsc	1

Part 2: SP: Left level 6 mediastinal lymph nodes [REDACTED] [REDACTED])

Block	Sect.	Site	PCs
1		fsc	1

Part 3: SP: Level seven mediastinal lymph nodes [REDACTED] [REDACTED]

Block	Sect.	Site	PCs
1		fsca	1
1		fsch	1
1		fsco	1

Part 4: SP: Left level eleven mediastinal lymph nodes [REDACTED]

Block	Sect.	Site	PCs
1		ln	1

Part 5: SP: Level five mediastinal lymph nodes [REDACTED]

Block	Sect.	Site	PCs
1		ln	1

Part 6: SP: Left posterior hilar level eleven lymph nodes [REDACTED]

Block	Sect.	Site	PCs
2		ln	2

Part 7: SP: Left level eleven interlobar nodes [REDACTED]

Block	Sect.	Site	PCs
3		ln	3

** Continued on next page **

[page 5 of 5]
Part 8: SP: Left upper lobe lung () Page 5 of 5

Block	Sect.	Site	PCs
14		{not entered}	14

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN. ()
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN. ()
PERMANENT DIAGNOSIS: SAME.
- 3) FROZEN SECTION DIAGNOSIS: BENIGN. ()
PERMANENT DIAGNOSIS: SAME.

** End of Report **

Source: NCI Genomic Data Commons file fe61fb55-f79a-40e2-a953-8a62827cf81e (TCGA-39-5021.84D7DC8E-29CD-4ADC-93EA-CDA77CF855B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).